Somatic mutation profile of tumor specimen TCGA-29-1699-01A (aliquot TCGA-29-1699-01A-01W-0633-09) from TCGA case TCGA-29-1699, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.9 years (21,130 days).
Specimen TCGA-29-1699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcf7ff4c-900a-46a5-802a-d946672379cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1699-10A (Blood Derived Normal), aliquot TCGA-29-1699-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/977b7374-2d18-455b-9909-5e3c83d7b390

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 18, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 81/115 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADM | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV63720557; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2926G>A p.D976N | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150618994; called by muse, mutect2, varscan2
- CAMK2D | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV56432791; called by muse, mutect2, varscan2
- CASP8 | c.1301C>T p.P434L (on ENST00000432109 / NM_033355.3; = p.P451L on NM_001228.4) | Missense Mutation (SNP) | VAF 108/188 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV51852709; called by muse, varscan2
- CENPF | c.3545_3548del p.E1182Vfs*21 | Frame Shift Del (DEL) | VAF 67/154 reads (44%) | catalogued as rs567266370; called by mutect2, pindel, varscan2
- CEP250 | c.7127G>A p.R2376H | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs374274791, COSV61168872, COSV61170900; called by muse, mutect2, varscan2
- COL14A1 | c.4039C>A p.P1347T | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV52857779; called by muse, mutect2, varscan2
- COL6A5 | c.6568G>A p.D2190N (on ENST00000312481; = p.D2186N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV55205568; called by muse, mutect2, varscan2
- CORO2B | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs546189688, COSV55950213, COSV55954251; called by muse, mutect2, varscan2
- CREBBP | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52127337; called by muse, mutect2, varscan2
- CSN2 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV61992310; called by muse, mutect2, varscan2
- DAP3 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 35/276 reads (13%) | catalogued as COSV58021217; called by muse, mutect2, varscan2
- DENND5A | c.2062A>T p.T688S | Missense Mutation (SNP) | VAF 109/491 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60234668; called by muse, mutect2, varscan2
- DNAJC6 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140156759, COSV54779569; called by muse, mutect2, varscan2
- DOK5 | c.909A>T p.R303S | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as COSV99374120; called by muse, mutect2
- DOLK | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV58281169; called by muse, mutect2, varscan2
- EPHX1 | c.539T>A p.V180D | Missense Mutation (SNP) | VAF 150/269 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55301587; called by muse, mutect2, varscan2
- FILIP1L | c.880G>C p.E294Q (on ENST00000354552 / NM_182909.3; = p.E54Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/675 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV58770415; called by muse, mutect2, varscan2
- GDI1 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99341064; called by muse, mutect2
- IQCH | c.1610C>G p.P537R | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60054531; called by muse, mutect2, varscan2
- ITGA1 | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50884761; called by muse, mutect2, varscan2
- ITGAD | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs369360258; called by muse, mutect2, varscan2
- JAG1 | c.724C>G p.H242D | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99653050; called by muse, mutect2
- KCNH1 | c.613A>T p.T205S | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55086519; called by muse, mutect2, varscan2
- LATS1 | c.2680T>A p.L894I | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV53592884; called by muse, mutect2, varscan2
- LPA | c.2460G>T p.R820S | Missense Mutation (SNP) | VAF 695/1808 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as COSV60303679; called by muse, mutect2, varscan2
- LRRK2 | c.3449A>C p.E1150A | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV54156649; called by muse, mutect2, varscan2
- LTA4H | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57382886; called by muse, mutect2, varscan2
- MAP2 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV52294926; called by muse, mutect2, varscan2
- MAP3K10 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 351/383 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53422947; called by muse, mutect2, varscan2
- MASTL | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.231); catalogued as COSV60911211; called by muse, mutect2, varscan2
- MBTPS1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.283); catalogued as rs749480313, COSV58571199; called by muse, mutect2, varscan2
- NLRP8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 135/221 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149738419; called by muse, mutect2, varscan2
- NRSN2 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV101206801, COSV66526981; called by muse, mutect2, varscan2
- OR52A5 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 54/175 reads (31%) | catalogued as COSV56615550; called by muse, mutect2, varscan2
- OR8A1 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 88/600 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV99420630; called by muse, mutect2, varscan2
- OR8I2 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs755472602, COSV56168406; called by muse, mutect2, varscan2
- PHLDB2 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 244/960 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV67312480; called by muse, mutect2, varscan2
- PIGT | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV54126815; called by muse, mutect2, varscan2
- PLA2G3 | c.120C>G p.N40K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV53210282; called by muse, mutect2, varscan2
- PLCXD2 | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67340605; called by muse, mutect2, varscan2
- QRFPR | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV57677763; called by muse, mutect2, varscan2
- SLC5A9 | c.1867T>C p.W623R | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1457223742, COSV52584038; called by muse, mutect2, varscan2
- SLC7A8 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748388088, COSV57554512; called by muse, mutect2, varscan2
- SORBS2 | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1233273935, COSV52993794; called by muse, mutect2, varscan2
- STAT6 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1229564909, COSV55671725, COSV55673226; called by muse, mutect2, varscan2
- SYNCRIP | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1335249487, COSV62288260; called by muse, mutect2, varscan2
- SYT11 | c.412A>T p.S138C | Missense Mutation (SNP) | VAF 95/657 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV64174858; called by muse, mutect2, varscan2
- TTN | c.83576T>A p.I27859N (on ENST00000591111; = p.I20435N on NM_003319.4) | Missense Mutation (SNP) | VAF 58/119 reads (49%) | PolyPhen possibly damaging (0.885); catalogued as COSV60127999; called by muse, mutect2, varscan2
- VCL | c.2540C>G p.P847R | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53009406, COSV53010679; called by muse, mutect2, varscan2
- WDR37 | c.1239-1G>A p.X413_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV54129412; called by muse, mutect2, varscan2
- ZNF410 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs150297098, COSV57911076; called by muse, mutect2
- ZNF528 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs780654618, COSV64619796; called by muse, mutect2, varscan2
- ZNF540 | c.1633C>T p.H545Y | Missense Mutation (SNP) | VAF 76/832 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs761814083, COSV100329735; called by muse, mutect2
- CSRNP2 | c.676_687delinsCTG p.C226_S229delinsL | In Frame Del (DEL) | VAF 51/174 reads (29%) | called by pindel, varscan2*
- FAM91A1 | c.331dup p.S111Kfs*3 | Frame Shift Ins (INS) | VAF 45/225 reads (20%) | called by mutect2, pindel, varscan2
- NOL4 | c.360del p.P121Qfs*31 | Frame Shift Del (DEL) | VAF 137/724 reads (19%) | called by pindel, varscan2
- PSMF1 | c.130-1G>C p.X44_splice | Splice Site (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- ADAMTS3 | c.2943C>G p.T981= | Silent (SNP) | VAF 106/176 reads (60%) | catalogued as COSV54394155, COSV99711168; called by muse, mutect2, varscan2
- CACNA1S | c.1575C>T p.S525= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs771788360, COSV62940583; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1996C>T p.L666= (on ENST00000361735 / NM_015935.5; = p.L580= on NM_014955.3) | Silent (SNP) | VAF 39/279 reads (14%) | catalogued as COSV62283261; called by muse, mutect2, varscan2
- EIF2B1 | c.822C>T p.D274= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV53016416; called by muse, mutect2, varscan2
- EPHA3 | c.1629C>T p.V543= | Silent (SNP) | VAF 62/278 reads (22%) | catalogued as COSV60710504; called by muse, mutect2, varscan2
- ESAM | c.549C>G p.V183= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99631896; called by muse, mutect2
- FAM187B | c.888C>T p.F296= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV61201375, COSV61201708; called by muse, mutect2, varscan2
- FAT3 | c.7080C>T p.C2360= | Silent (SNP) | VAF 63/215 reads (29%) | catalogued as rs548864892, COSV53124776; called by muse, mutect2, varscan2
- FBXL4 | c.1854C>T p.S618= | Silent (SNP) | VAF 67/385 reads (17%) | catalogued as COSV57747511; called by muse, mutect2, varscan2
- FNDC7 | c.1425T>C p.N475= | Silent (SNP) | VAF 72/249 reads (29%) | catalogued as rs1378923910, COSV54754765; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 57/428 reads (13%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- MICAL2 | c.1770C>T p.I590= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV56317164; called by muse, mutect2
- MUC17 | c.3603T>A p.P1201= | Silent (SNP) | VAF 155/771 reads (20%) | catalogued as COSV60291730; called by muse, mutect2, varscan2
- OR2T2 | c.903T>C p.A301= | Silent (SNP) | VAF 24/264 reads (9%) | catalogued as COSV100737690; called by muse, varscan2
- OR2T35 | c.900T>C p.A300= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV100442304; called by muse, mutect2
- PNLIPRP2 | c.1197A>G p.A399= (on ENST00000611850; = p.A400= on NM_005396.5) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV53944384; called by muse, mutect2, varscan2
- SERBP1 | c.129G>A p.G43= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV63413734; called by muse, mutect2, varscan2
- SLC12A6 | c.609C>A p.I203= (on ENST00000354181 / NM_001365088.1; = p.I152= on NM_005135.2) | Silent (SNP) | VAF 33/373 reads (9%) | catalogued as COSV99270782, COSV99272320; called by muse, mutect2
- CENPN | chr16:81032637 G>T | 3'Flank (SNP) | VAF 18/57 reads (32%) | catalogued as COSV55145128, COSV55146514; called by muse, mutect2, varscan2
